Somatic mutation profile of tumor specimen TCGA-29-1707-01A (aliquot TCGA-29-1707-01A-01W-0633-09) from TCGA case TCGA-29-1707, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 41.1 years (15,017 days).
Specimen TCGA-29-1707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e9f9dcd-06dd-4775-a1d9-663558730a5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1707-10A (Blood Derived Normal), aliquot TCGA-29-1707-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfb7b1f2-ae1b-4f43-8846-8101dceecc01

The open-access MAF lists 60 somatic variants for this specimen: 44 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 13, Intron 3, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 36/55 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.4035C>G p.D1345E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100622801; called by muse, mutect2
- ACSM2A | c.1541A>T p.Q514L (on ENST00000219054; = p.Q435L on NM_001308169.2) | Missense Mutation (SNP) | VAF 110/273 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1567377251, COSV54590799, COSV99525534; called by muse, mutect2, varscan2
- AMIGO2 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.412); catalogued as rs1307239754, COSV56975833; called by muse, mutect2, varscan2
- ATRX | c.4800G>T p.K1600N | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100970656; called by muse, mutect2
- BAZ2B | c.2927C>A p.A976E | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54277129; called by muse, mutect2
- BIN2 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV57208564; called by muse, mutect2, varscan2
- CDH5 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs1007635454, COSV58520454; called by muse, mutect2, varscan2
- CERS3 | c.542A>T p.Y181F | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52575799; called by muse, mutect2, varscan2
- CLCA4 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 169/431 reads (39%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.875); catalogued as COSV55367901, COSV55371672; called by muse, mutect2, varscan2
- COL11A1 | c.2911C>A p.P971T | Missense Mutation (SNP) | VAF 142/303 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62201301; called by muse, mutect2, varscan2
- COL7A1 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs748854484, COSV60395226, COSV60404401; called by muse, mutect2, varscan2
- CSMD2 | c.477C>A p.D159E | Missense Mutation (SNP) | VAF 234/546 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs762773761, COSV53972785; called by muse, mutect2, varscan2
- DNAH10 | c.5654T>G p.M1885R (on ENST00000409039; = p.M1824R on NM_207437.3) | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV69004176; called by muse, mutect2, varscan2
- DNAH5 | c.13844G>T p.R4615L | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54232489; called by muse, mutect2
- DUOXA1 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as rs766903143, COSV50995122; called by muse, mutect2, varscan2
- GSTA2 | c.456G>C p.K152N | Missense Mutation (SNP) | VAF 27/445 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV101534042; called by muse, mutect2
- JAG1 | c.3440C>G p.S1147C | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as COSV54763901; called by muse, mutect2, varscan2
- KIF21A | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV62779053; called by muse, mutect2, varscan2
- KMT2C | c.3797G>T p.G1266V | Missense Mutation (SNP) | VAF 145/538 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV51513057; called by muse, mutect2, varscan2
- MSANTD3 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs1045989031, COSV58498166; called by muse, mutect2, varscan2
- MUC16 | c.34425C>G p.F11475L | Missense Mutation (SNP) | VAF 277/902 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.298); catalogued as COSV67465439, COSV67500562, COSV67503141; called by muse, mutect2, varscan2
- NLRP5 | c.2581T>A p.L861I | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV101173630; called by muse, mutect2
- OR1J2 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 75/461 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.922); catalogued as COSV58945493; called by muse, mutect2, varscan2
- OR5AS1 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 160/404 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1478766178, COSV57981437, COSV57983607; called by muse, mutect2, varscan2
- PCDH11X | c.1633A>T p.N545Y | Missense Mutation (SNP) | VAF 97/231 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53452795; called by muse, mutect2, varscan2
- PRH2 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); catalogued as COSV101113305; called by muse, mutect2
- SAMSN1 | c.703A>C p.N235H | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53478758; called by muse, mutect2, varscan2
- SDK1 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750483213, COSV67391874; called by muse, mutect2, varscan2
- SPEM2 | c.240C>G p.D80E | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV60367969; called by muse, mutect2, varscan2
- SPRY3 | c.429C>A p.H143Q | Missense Mutation (SNP) | VAF 95/588 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV57144731; called by muse, mutect2, varscan2
- THOC2 | c.1885A>T p.K629* | Nonsense Mutation (SNP) | VAF 59/152 reads (39%) | catalogued as COSV55557370; called by muse, mutect2, varscan2
- TMC4 | c.1194C>G p.I398M (on ENST00000617472 / NM_001145303.3; = p.I392M on NM_144686.4) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as COSV55829180; called by muse, mutect2, varscan2
- TMPRSS11B | c.553A>T p.I185F | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100219344, COSV60294522; called by muse, mutect2
- WDFY3 | c.10415G>T p.R3472I | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55709576, COSV55716211; called by muse, mutect2, varscan2
- ZNF418 | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 22/350 reads (6%) | catalogued as rs1303439394, COSV68675910; called by muse, mutect2
- ZNF471 | c.813C>G p.F271L | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57294060; called by muse, mutect2, varscan2
- ZP2 | c.370A>T p.S124C | Missense Mutation (SNP) | VAF 88/217 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV54817474; called by muse, mutect2, varscan2
- ATP6V0A2 | c.998_1027del p.A333_L342del | In Frame Del (DEL) | VAF 25/96 reads (26%) | called by mutect2, pindel, varscan2
- C3orf33 | c.762del p.E255Kfs*18 (on ENST00000340171 / NM_001308229.2; = p.E212Kfs*18 on NM_173657.2) | Frame Shift Del (DEL) | VAF 52/159 reads (33%) | called by mutect2, pindel, varscan2
- IGHV2-5 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LAMB4 | c.840G>C p.M280I | Missense Mutation (SNP) | VAF 15/340 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2
- PPP2R2A | c.968_972+19del p.X323_splice | Splice Site (DEL) | VAF 23/36 reads (64%) | called by mutect2, pindel, varscan2
- SMCR8 | c.2001C>G p.S667R | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2
- ADAMTSL2 | c.516G>A p.K172= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs747939263, COSV63206906; called by muse, mutect2, varscan2
- AFF2 | c.429A>T p.I143= | Silent (SNP) | VAF 941/1634 reads (58%) | catalogued as COSV60685116; called by muse, mutect2, varscan2
- ANXA3 | c.63A>C p.S21= | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as COSV99363690, COSV99363753; called by muse, mutect2
- GPR107 | c.645T>C p.D215= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV61283389; called by muse, mutect2, varscan2
- MAN2C1 | c.894C>T p.S298= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV51249699, COSV99145662; called by muse, mutect2, varscan2
- MARCO | c.87C>T p.F29= | Silent (SNP) | VAF 21/185 reads (11%) | catalogued as rs759366698, COSV59057298; called by muse, mutect2, varscan2
- MOXD1 | c.957T>C p.D319= | Silent (SNP) | VAF 85/112 reads (76%) | catalogued as COSV60950198; called by muse, mutect2, varscan2
- OR5F1 | c.27G>T p.L9= | Silent (SNP) | VAF 9/159 reads (6%) | catalogued as COSV53545725, COSV53548109, COSV99558528; called by muse, mutect2
- PCIF1 | c.1437C>T p.F479= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs746785031, COSV59820781; called by muse, mutect2, varscan2
- POMT1 | c.624G>T p.V208= | Silent (SNP) | VAF 33/321 reads (10%) | catalogued as COSV61228059; called by muse, mutect2, varscan2
- SLFN12 | c.1419T>C p.T473= | Silent (SNP) | VAF 86/107 reads (80%) | catalogued as rs773580554, COSV59227984; called by muse, mutect2, varscan2
- TAS2R41 | c.909C>T p.G303= | Silent (SNP) | VAF 41/133 reads (31%) | catalogued as COSV68765974; called by muse, mutect2, varscan2
- ZNF202 | c.813T>C p.C271= | Silent (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
- ADARB2 | c.1865-1492C>T | Intron (SNP) | VAF 8/97 reads (8%) | catalogued as rs768374486, COSV67182801; called by muse, mutect2
- RIMS2 | c.1692+165T>C | Intron (SNP) | VAF 69/157 reads (44%) | catalogued as COSV51731850; called by muse, mutect2, varscan2
- TMEM44 | c.1318-4409C>T | Intron (SNP) | VAF 34/140 reads (24%) | catalogued as rs865921529, COSV56452476; called by muse, mutect2, varscan2
